Gene-level copy-number profile of tumor specimen HCM-SANG-1326-C15-01A-01D-A80T-32 from HCMI case HCM-SANG-1326-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-1326-C15-01A-01D-A80T-32: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b72fe717-955b-4a0e-9dd4-2aebf8b123b5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1326-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/14b81e28-b3dc-49b4-bfef-a9c660b416b9

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 524; copy number 1: 1,919; copy number 2: 20,465; copy number 3: 29,228; copy number 4: 5,374; copy number 5: 894; copy number 6: 133; copy number 7: 22; copy number 8: 9; copy number 9: 195; copy number 21: 32; copy number 22: 4; copy number 23: 4; copy number 24: 5; copy number 26: 24; copy number 38: 13; copy number 39: 41; copy number 242: 16.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:4,117,925–4,157,443, 4 genes: AC116562.1, OR7E103P, UNC93B4, OR7E99P.
- chr17:57,253,236–57,684,689, 8 genes (within-gene range 0–3): AC091181.2, MSI2, AC091181.1, AC015883.1, AC007431.2, AC007431.3, AC007431.1, RN7SL449P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 365 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:37,052,626–37,183,689, 1 gene, copy number 39 (within-gene range 2–39): LRRFIP2.
- chr3:37,134,658–41,260,096, 93 genes, copy number 21–39 (within-gene range 2–39) (broad region; genes not listed).
- chr7:98,846,488–99,504,857, 22 genes, copy number 7 (within-gene range 3–7): TMEM130, TRRAP, MIR3609, AC004893.2, RNF14P3, SMURF1, AC004893.1, KPNA7, MYH16, AC004834.1, AC004922.1, ARPC1A, ARPC1B, PDAP1, BUD31, PTCD1, ATP5MF-PTCD1, CPSF4, AC073063.1, ATP5MF, ZNF789, ZNF394.
- chr9:30,388,935–36,677,683, 204 genes, copy number 8–9 (broad region; genes not listed).
- chr10:120,354,701–121,615,839, 16 genes, copy number 242: RPL21P16, AC073587.1, PLPP4, LINC01561, AC023282.1, WDR11-AS1, AL391425.1, WDR11, AC010998.2, AC010998.1, AC010998.3, RPL19P16, LINC01153, RN7SKP167, FGFR2, AC009988.1.
- chr18:21,650,901–22,419,294, 29 genes, copy number 24–26: ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1.

Autosomal genes at a single copy (total copy number 1): 1,577. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
